Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6518, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6518-01A (Primary Tumor).

[page 1 of 2]
Examination: Histopathological examination

Material: **Multiple organ resection – stomach**

TCGA – D7 – 6518

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of stomach. Stomach with spleen.**

Examination performed on:

Macroscopic description:

Sent material consisting of the stomach, cut out along the greater curvature, sized 16 x 14 cm with the omentum sized 14 x 18 x 2 cm. Thickening over the area of 8.5 x 14 cm in the part of the cardia, on the lesser curvature, on the front and back walls, with an ulceration sized 5 x 3 cm. Spleen sized 6.5 x 5.4 x 4 cm with a thickened capsule and numerous glassy nodules.

Microscopic description:

Adenocarcinoma mucocellulare partim tubulare et mucinosum invasivum ventriculi (G3) (Lauren's mixed type).

The tumour invades through the full thickness of the stomach wall, reaches the surface of the peritoneum and infiltrates the omentum fat tissue.

Incision line in the oesophagus and pylorus free of neoplastic lesions.

LYMPH NODES:

- (periorificial): metastases carcinomatosae in lymphonodis No IV/IV.
- Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.
- (lesser curvature): metastases carcinomatosae in lymphonodis (No X/XII).
- Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.
- (greater curvature): metastases carcinomatosae in lymphonodo (No I/I).
- Infiltratio carcinomatosa capsulae lymphonodori et telae adiposae perinodalis.
- (spleen hilus): metastases carcinomatosae in lymphonodis (No II/IV).
- Spleen – hyperaemia, persplenitis cartilaginea

[page 2 of 2]
Histopathological diagnosis:

Adenocarcinoma mucocellulare partim tubulare et mucinosum invasivum ventriculi. Mucocellular and partially tubular and mucinous invasive adenocarcinoma of the stomach. /

Metastases carcinomatosae in lymphonodorum (No XVII/XX). Cancer metastases of the lymph nodes (No XVII/XX)

(G3, pT2, pN3)

Source: NCI Genomic Data Commons file e65638ce-190c-4342-8760-f994c7da5b57 (TCGA-D7-6518.B78CEAB7-F101-43B5-867F-66A3A0B6D5CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).